Somatic mutation profile of tumor specimen ALCH-ADAD-TTP1-A (aliquot ALCH-ADAD-TTP1-A-1-0-D-A532-36) from ALCHEMIST case ALCH-ADAD, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 58.7 years (21,447 days).
Specimen ALCH-ADAD-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1c10abaf-0936-4687-98c7-465529bf1ac9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-ADAD-NB1-A (Blood Derived Normal), aliquot ALCH-ADAD-NB1-A-1-0-D-A532-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b37ec82a-ddb8-4438-8997-2c59964bcf2c

The open-access MAF lists 62 somatic variants for this specimen: 50 protein-altering or splice-affecting, 8 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, Silent 8, Frame Shift Del 5, Nonsense Mutation 3, Intron 2, 5'UTR 1, RNA 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 80/629 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AGER | c.1150G>A p.E384K | Missense Mutation (SNP) | VAF 37/440 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.138); catalogued as rs745528625; called by muse, mutect2
- ASXL3 | c.6107C>T p.P2036L | Missense Mutation (SNP) | VAF 32/145 reads (22%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.996); catalogued as rs778714083; called by muse, mutect2, varscan2
- COL4A5 | c.4819G>T p.A1607S | Missense Mutation (SNP) | VAF 60/942 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.95); catalogued as COSV60368274; called by muse, mutect2
- DCAF12L1 | c.189G>T p.W63C | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.221); catalogued as COSV64422911; called by muse, mutect2, varscan2
- DCAF4L2 | c.485C>T p.S162L | Missense Mutation (SNP) | VAF 47/295 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.963); catalogued as rs748853957, COSV100150629, COSV60480352; called by muse, mutect2, varscan2
- DLC1 | c.722C>A p.P241H | Missense Mutation (SNP) | VAF 26/196 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.257); catalogued as rs149776829; called by muse, mutect2, varscan2
- DST | c.10954A>G p.I3652V (on ENST00000361203 / NM_001374722.1; = p.I1240V on NM_015548.5) | Missense Mutation (SNP) | VAF 33/260 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.237); catalogued as rs1483998442; called by muse, mutect2, varscan2
- MARCHF11 | c.653G>C p.R218T | Missense Mutation (SNP) | VAF 39/258 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.082); catalogued as COSV60133758; called by muse, mutect2, varscan2
- MYLK | c.640G>A p.G214S | Missense Mutation (SNP) | VAF 72/756 reads (10%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as rs200452099; called by muse, mutect2
- NPR1 | c.2011C>T p.R671C | Missense Mutation (SNP) | VAF 40/359 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766674601, COSV64117729; called by muse, mutect2, varscan2
- NRK | c.1744C>T p.R582* | Nonsense Mutation (SNP) | VAF 18/240 reads (8%) | catalogued as rs762084637, COSV54589566, COSV54599067; called by muse, mutect2
- NRXN1 | c.4132C>A p.P1378T | Missense Mutation (SNP) | VAF 30/250 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as COSV100639851; called by muse, mutect2, varscan2
- SLC9A6 | c.1970C>T p.P657L | Missense Mutation (SNP) | VAF 13/252 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.103); catalogued as rs782228236; called by muse, mutect2
- SV2A | c.1330C>T p.R444W | Missense Mutation (SNP) | VAF 30/568 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs117711516, COSV100975285, COSV64965879; called by muse, mutect2
- ANKRD36 | c.701G>T p.G234V | Missense Mutation (SNP) | VAF 36/505 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); called by muse, mutect2
- AP3B1 | c.2861del p.C954Lfs*47 | Frame Shift Del (DEL) | VAF 55/404 reads (14%) | called by mutect2, pindel, varscan2
- ATRX | c.1775C>G p.P592R | Missense Mutation (SNP) | VAF 36/497 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- CDC20 | c.206C>A p.T69N | Missense Mutation (SNP) | VAF 41/278 reads (15%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2, varscan2
- CHD7 | c.2581G>T p.A861S | Missense Mutation (SNP) | VAF 31/301 reads (10%) | SIFT tolerated (0.71); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- CNOT2 | c.1387G>T p.E463* | Nonsense Mutation (SNP) | VAF 25/251 reads (10%) | called by muse, mutect2, varscan2
- DNA2 | c.1573A>G p.R525G | Missense Mutation (SNP) | VAF 32/171 reads (19%) | SIFT tolerated (0.53); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EIF2AK4 | c.4455T>A p.H1485Q | Missense Mutation (SNP) | VAF 46/577 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); called by muse, mutect2
- F5 | c.4481C>A p.S1494* | Nonsense Mutation (SNP) | VAF 60/864 reads (7%) | called by muse, mutect2
- GAB4 | c.365A>G p.D122G | Missense Mutation (SNP) | VAF 58/491 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GALK2 | c.952C>T p.P318S | Missense Mutation (SNP) | VAF 27/163 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- GAS6 | c.1463A>G p.Y488C | Missense Mutation (SNP) | VAF 32/198 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); called by mutect2, varscan2
- GREB1L | c.3635del p.P1212Hfs*21 | Frame Shift Del (DEL) | VAF 8/54 reads (15%) | called by mutect2, pindel, varscan2
- GRK7 | c.269T>A p.V90E | Missense Mutation (SNP) | VAF 13/125 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.327); called by muse, mutect2, varscan2
- HMGCS2 | c.259G>T p.G87C | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HNRNPL | c.694G>T p.V232F | Missense Mutation (SNP) | VAF 14/228 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- IGKV1-17 | c.53del p.P18Qfs*9 | Frame Shift Del (DEL) | VAF 77/712 reads (11%) | called by pindel, varscan2
- KDM3A | c.1531A>G p.K511E | Missense Mutation (SNP) | VAF 13/242 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.313); called by muse, mutect2
- LRRC75A | c.524A>C p.D175A (on ENST00000470794 / NM_001113567.3; = p.R136S on NM_207387.4) | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.269); called by mutect2, varscan2
- MFAP3L | c.635C>T p.T212I | Missense Mutation (SNP) | VAF 28/125 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NKX2-1 | c.849dup p.G284Rfs*125 | Frame Shift Ins (INS) | VAF 5/50 reads (10%) | called by pindel, varscan2
- NLE1 | c.580A>T p.T194S | Missense Mutation (SNP) | VAF 37/417 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.089); called by muse, mutect2
- OR10A3 | c.224C>G p.A75G | Missense Mutation (SNP) | VAF 22/185 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PARVB | c.496G>A p.A166T | Missense Mutation (SNP) | VAF 16/124 reads (13%) | SIFT tolerated (0.43); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PCDHA7 | c.1711G>C p.G571R | Missense Mutation (SNP) | VAF 82/602 reads (14%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PDE12 | c.860A>G p.K287R | Missense Mutation (SNP) | VAF 34/539 reads (6%) | SIFT tolerated (0.32); PolyPhen benign (0.02); called by muse, mutect2
- PTCD3 | c.894T>G p.I298M | Missense Mutation (SNP) | VAF 28/179 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ROBO2 | c.3534T>A p.F1178L | Missense Mutation (SNP) | VAF 52/381 reads (14%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2, varscan2
- SIGLEC7 | c.758C>A p.T253K | Missense Mutation (SNP) | VAF 27/292 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- SRCIN1 | c.3289G>A p.A1097T (on ENST00000621492; = p.A1063T on NM_025248.3) | Missense Mutation (SNP) | VAF 30/149 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- TMEM132C | c.2914del p.V972Cfs*27 | Frame Shift Del (DEL) | VAF 23/192 reads (12%) | called by mutect2, pindel, varscan2
- TRPM5 | c.2863G>T p.V955F | Missense Mutation (SNP) | VAF 27/218 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- XYLT1 | c.554del p.P185Hfs*9 | Frame Shift Del (DEL) | VAF 111/746 reads (15%) | called by mutect2, pindel, varscan2
- ZFP91 | c.1097A>G p.H366R | Missense Mutation (SNP) | VAF 23/249 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.666); called by muse, mutect2
- ZNF236 | c.1049G>T p.S350I | Missense Mutation (SNP) | VAF 66/493 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ABCC1 | c.432A>T p.V144= | Silent (SNP) | VAF 50/477 reads (10%) | called by muse, mutect2, varscan2
- CNOT2 | c.1386G>T p.V462= | Silent (SNP) | VAF 26/252 reads (10%) | called by muse, mutect2, varscan2
- DCAF12L2 | c.984C>T p.H328= | Silent (SNP) | VAF 22/187 reads (12%) | catalogued as rs763667428; called by muse, mutect2, varscan2
- OR4E2 | c.420C>A p.V140= | Silent (SNP) | VAF 20/221 reads (9%) | catalogued as rs1427700942, COSV100330123; called by muse, mutect2
- SAMD9L | c.3162G>T p.L1054= | Silent (SNP) | VAF 27/209 reads (13%) | called by muse, mutect2, varscan2
- SLITRK5 | c.1824G>T p.S608= | Silent (SNP) | VAF 62/453 reads (14%) | catalogued as rs768554234, COSV100280419, COSV61527230; called by muse, mutect2, varscan2
- SMC1B | c.2832G>A p.S944= | Silent (SNP) | VAF 38/265 reads (14%) | catalogued as rs546593612; called by muse, mutect2, varscan2
- VPS13C | c.3762G>A p.Q1254= (on ENST00000644861 / NM_020821.3; = p.Q1211= on NM_017684.5) | Silent (SNP) | VAF 84/471 reads (18%) | called by muse, mutect2, varscan2
- ANKS1B | c.3067-6785T>A | Intron (SNP) | VAF 36/222 reads (16%) | called by muse, mutect2, varscan2
- HES2 | c.-6C>A | 5'UTR (SNP) | VAF 17/105 reads (16%) | called by muse, mutect2
- MAP2K1 | c.1022+45T>A | Intron (SNP) | VAF 58/354 reads (16%) | called by muse, mutect2, varscan2
- MSL3P1 | n.601C>T | RNA (SNP) | VAF 21/400 reads (5%) | catalogued as rs940195273; called by muse, mutect2
